CCDI case PBBICS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/aa48bd61-574c-4121-a881-9bec54a6c199

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Gliosarcoma: ICD-O-3 morphology code: 9442/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 17.4 years (6,373 days).

Biospecimens (2 samples)
- Sample 0D8Y6M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D8Y6N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
